Somatic mutation profile of tumor specimen TCGA-3H-AB3L-01A (aliquot TCGA-3H-AB3L-01A-11D-A39R-32) from TCGA case TCGA-3H-AB3L, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 60.2 years (21,972 days).
Specimen TCGA-3H-AB3L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9a7cfb2-0918-4ad8-ac71-725887af6f47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3H-AB3L-10A (Blood Derived Normal), aliquot TCGA-3H-AB3L-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/146d9051-ab44-44dc-8b42-a10bb9ea818a

The open-access MAF lists 29 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, Splice Site 4, Frame Shift Del 3, 3'Flank 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 56/111 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ARNT2 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 17/149 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs966637310, COSV100308769; called by muse, mutect2, varscan2
- GAS2L3 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as COSV57157222; called by muse, mutect2, varscan2
- COG7 | c.287_288del p.K96Ifs*2 | Frame Shift Del (DEL) | VAF 22/84 reads (26%) | called by mutect2, pindel, varscan2
- DAAM1 | c.1471_1488del p.K491_K496del | In Frame Del (DEL) | VAF 10/79 reads (13%) | called by mutect2, pindel, varscan2
- DDX3X | c.486del p.Y162* (on ENST00000399959; = p.Y163* on NM_001356.5) | Frame Shift Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- EMC2 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- EPN2 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ERG | c.892+2T>G p.X298_splice (on ENST00000398919 / NM_001243428.1; = p.X274_splice on NM_004449.4) | Splice Site (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- FAM131A | c.509A>C p.D170A (on ENST00000310585; = p.D201A on NM_144635.5) | Missense Mutation (SNP) | VAF 61/173 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- H2BC9 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- IGSF21 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGA8 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT tolerated (0.61); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- KERA | c.886+2T>A p.X296_splice | Splice Site (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2
- LEXM | c.1097C>T p.T366I | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- POLR2G | c.8_9del p.Y3Sfs*49 | Frame Shift Del (DEL) | VAF 70/279 reads (25%) | called by mutect2, pindel, varscan2
- SND1 | c.590-2A>G p.X197_splice | Splice Site (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- SNTB2 | c.1149-1G>C p.X383_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- ZNF423 | c.522C>G p.F174L (on ENST00000563137 / NM_001379286.1; = p.F166L on NM_015069.4) | Missense Mutation (SNP) | VAF 44/420 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLTC | c.3447C>T p.N1149= | Silent (SNP) | VAF 20/61 reads (33%) | called by muse, mutect2
- ITGA10 | c.3396A>T p.G1132= | Silent (SNP) | VAF 37/102 reads (36%) | called by muse, mutect2, varscan2
- KCNG1 | c.390C>T p.F130= | Silent (SNP) | VAF 146/512 reads (29%) | catalogued as rs373952658; called by muse, mutect2, varscan2
- LRRC47 | c.273G>C p.L91= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as rs1297219227; called by muse, mutect2, varscan2
- SLC9A2 | c.2091C>T p.D697= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs759669566, COSV52135011; called by muse, mutect2, varscan2
- SUMO2 | c.30C>T p.V10= | Silent (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- UQCRC1 | c.375C>T p.T125= | Silent (SNP) | VAF 29/99 reads (29%) | called by muse, mutect2, varscan2
- ZFYVE9 | c.39C>T p.D13= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99053860; called by mutect2, varscan2
- ALMS1P1 | chr2:73701270 G>A | 3'Flank (SNP) | VAF 108/336 reads (32%) | catalogued as rs775665665; called by muse, mutect2, varscan2
- PRR12 | chr19:49593402 C>T | 5'Flank (SNP) | VAF 153/425 reads (36%) | called by muse, mutect2, varscan2
